Surgical pathology report (de-identified scan), TCGA case TCGA-DX-A3UA, project TCGA-SARC (Sarcoma), tissue source site Memorial Sloan Kettering, specimen TCGA-DX-A3UA-01A (Primary Tumor).

[page 1 of 3]
DEPARTMENT OF PATHOLOGY

SURGICAL PATHOLOGY REPORT

Patient: [REDACTED]

CC:

Patient Address: [REDACTED]

....

Clinical Diagnosis & History:
Right foot leiomyosarcoma.

Specimens Submitted:

1: SP: Right amputation of 4th and 5th metatarsal

DIAGNOSIS:

1. RIGHT FOOT, 4TH AND 5TH METATARSAL MASS, AMPUTATION:
- SPINDLE CELL SARCOMA , HIGH GRADE COMPATIBLE WITH LEIOMYOSARCOMA (4.5 CM IN GREATEST DIMENSION) OF THE 5TH METATARSAL BONE.
- THE TUMOR EXTENDS MEDIALY TO THE 4TH METATARSAL BONE AND INFEROLATERALLY THROUGH THE THE 5TH METATARSAL BONE INTO SOFT TISSUE APPROACHING DEEP DERMIS AND DISTALLY TO PROXIMAL ASPECT OF PHALANX.
- SURGICAL RESECTION MARGINS ARE FREE OF TUMOR.
- MITOTIC ACTIVITY : 7/10HPFS
- NECROSIS IS NOT IDENTIFIED.
- SKIN WITH SCAR.
- TUMOR SHOWS A PREDOMINANT HEMANGIOPERICYTIC PATTERN OF GROWTH.
- IMMUNOSTAINS REVEAL THAT THE TUMOR CELLS ARE FOCALLY POSITIVE FOR SMA, CALDESMON, CD34 AND S-100, AND NEGATIVE FOR AE1:AE3, CD-117 AND DESMIN. THESE FINDINGS SUPPORT THE ABOVE DIAGNOSIS.

Note. one of the immunohistochemistry and ISH tests were developed and their performance characteristics were determined by the Department of Pathology. They have not been cleared or approved by the US Food and Drug Administration. The FDA has determined that such clearance or approval is not necessary. These tests are used for clinical purposes. They should not be regarded as investigational or for research. This laboratory is certified under the Clinical Laboratory Improvement Amendments of 1988 (CLIA ' 88) as qualified to perform high complexity clinical laboratory testing.

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

*** Report Electronically Signed Out ***

** Continued on next page **

1CD-0-3

leiomyosarcoma, NOS
8890/3

Site: metatarsal bone
c40.3

5-12-12
RD

[page 2 of 3]
SURGICAL

Page 2 of 3

Gross Description:

1. The specimen is received fresh, labeled as "amputation of 4th and 5th metatarsal" consists of the 4th and 5th toe with intact nails and skin with 9.5 (anterior-posterior) x 4.0 (medial to lateral) x 4.8 (superior to inferior) cm soft tissue including bones (4th and 5th metatarsal bones and phalanges) attached. The lateral aspect of the specimen is covered by a 7.0 x 4.0 cm tan skin ellipse. Sections reveal a lobulated soft tan mass measuring 4.5 x 2.1 x 1.9 cm involving mid to distal 5th metatarsal bone extending medially to the 4th metatarsal bone and lateral-inferiorly to underlying soft tissue reaching within 0.2 cm of the skin. Medially the mass is confined by the 4th metatarsal bone. The mass is 4 cm from posterior, 1.8 cm from anterior, 1.2 cm from superior, and 0.5 cm from inferior and 1.1 cm from medial soft tissue margin. Also the mass is 2.2 cm from posterior and 1.2 cm from the anterior bone margin. The specimen is inked black for medial, blue for inferior, green for lateral, and yellow for posterior soft tissue margin. Photos are taken. TPS is taken. Representative sections are taken after decal.

Summary of Sections:

SIM superior (black) and inferior (blue) soft tissue margins, perpendicular
L lateral skin, perpendicular
M medial soft tissue margin
APM anterior (black) and posterior (yellow) soft tissue margin.
TM tumor with medial soft tissue margin
TS tumor with lateral skin.
A, D, I, M, N 4th metatarsal and phalangeal bone with the mass
B proximal bone margin
E, G, J, K, O, P mass of the 5th metatarsal and phalangeal bone
C, F, H, L lateral-inferior soft tissue and tumor.

Summary of Sections:

Part 1: SP: Right amputation of 4th and 5th metatarsal

Block	Sect. Site	PCs
1	A	1
1	APM	2
1	B	1
1	C	1
1	D	1
1	E	1
1	F	1
1	G	1
1	H	1
1	I	1
1	J	1
1	K	1

** Continued on next page **

[page 3 of 3]
SURGICAL

----- Page 3 of 3

2	L	2
1	M	1
1	MM	1
1	N	1
1	O	1
1	P	1
1	SIM	2
1	TM	1
1	TS	1

** End of Report **

TIPAA Discrepancy		/
Dual/Synchronous Primary No Mtd		/

Source: NCI Genomic Data Commons file 1e6b7e5e-09ba-4adb-b1a0-eb51703de22e (TCGA-DX-A3UA.35F73769-C1A4-4918-A604-6021621E1571.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).